Somatic mutation profile of tumor specimen TARGET-20-PASVZC-04A (aliquot TARGET-20-PASVZC-04A-01D) from TARGET case TARGET-20-PASVZC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (559 days).
Specimen TARGET-20-PASVZC-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 057d2492-54d6-494f-b6d6-45de76c788db.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASVZC-14A (Bone Marrow Normal), aliquot TARGET-20-PASVZC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea47376-3659-4dd4-a523-853e9579ce2b

The open-access MAF lists 15 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 7, Missense Mutation 5, Intron 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JMJD1C | c.7534G>A p.V2512I | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.663); catalogued as rs370544199; called by muse, mutect2, varscan2
- NRXN1 | c.558C>G p.D186E | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs772333323, COSV68016418; called by muse, mutect2, varscan2
- NRXN1 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs995509296, COSV68003380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPRC1 | c.4570C>A p.H1524N | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs144208253; called by muse, mutect2, varscan2
- ZNF469 | c.3697G>A p.G1233S (on ENST00000437464; = p.G1261S on NM_001367624.2) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs913053503; called by muse, mutect2, varscan2
- NCAM1 | c.1203C>T p.I401= (on ENST00000316851 / NM_181351.5; = p.I391= on NM_000615.7) | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs782542999, COSV57510143; called by muse, mutect2, varscan2
- ACTB | c.*375C>T | 3'UTR (SNP) | VAF 36/82 reads (44%) | catalogued as rs1166080296, COSV59320555; called by muse, mutect2, varscan2
- DICER1 | c.*1538G>A | 3'UTR (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- FGFR1 | c.92-580C>T | Intron (SNP) | VAF 20/65 reads (31%) | catalogued as rs768496921; called by muse, mutect2, varscan2
- IKZF1 | c.*1807C>T | 3'UTR (SNP) | VAF 59/146 reads (40%) | catalogued as rs998602033; called by muse, mutect2, varscan2
- IKZF1 | c.*3335G>A | 3'UTR (SNP) | VAF 83/198 reads (42%) | catalogued as rs1027109305; called by muse, mutect2
- PHF2 | c.*624C>A | 3'UTR (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- PTEN | c.*1131del | 3'UTR (DEL) | VAF 88/204 reads (43%) | catalogued as rs547262170; ClinVar: likely benign; called by mutect2, varscan2
- SYNRG | c.*3041G>T | 3'UTR (SNP) | VAF 42/124 reads (34%) | catalogued as rs183011035; called by muse, varscan2
- VPS11 | chr11:119067847 G>C | 5'Flank (SNP) | VAF 15/36 reads (42%) | catalogued as rs782083124; called by muse, mutect2, varscan2
